Gene-level copy-number profile of specimen HCM-CSHL-0239-C18-85A from HCMI case HCM-CSHL-0239-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.0 years (20,072 days).
Specimen HCM-CSHL-0239-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d383989-09b9-4711-b06e-29c9daf7c0d2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0239-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/40f306f8-b01d-4d6b-af65-8e6bbd107795

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 887; copy number 2: 12,555; copy number 3: 29,546; copy number 4: 11,624; copy number 5: 832; copy number 6: 556; copy number 7: 578; copy number 8: 728; copy number 9: 308; copy number 10: 749.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–2): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr15:20,803,505–21,058,440, 18 genes (within-gene range 0–2): AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–2): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–2): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,363 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,493 genes, copy number 7–10 (broad region; genes not listed).
- chr20:30,214,765–64,327,972, 870 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
